Gene-level copy-number profile of specimen HCM-SANG-0533-C20-85A-01D-A80T-32 from HCMI case HCM-SANG-0533-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Tumor grade: G2.
Specimen HCM-SANG-0533-C20-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5cc198e1-d268-422c-9198-8b048174c0f9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0533-C20-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/b1e84fff-a4f0-4002-a2ca-89c427ab11c9

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 2,069; copy number 1: 25,664; copy number 2: 23,339; copy number 3: 4,846; copy number 4: 1,941; copy number 5: 361; copy number 6: 36; copy number 7: 36; copy number 9: 13; copy number 11: 78; copy number 19: 16.

Homozygous deletions (total copy number 0; autosomes only): 2,069 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:74,026,015–79,522,203, 84 genes (broad region; genes not listed).
- chr1:80,373,364–80,646,791, 6 genes: AL606519.1, HNRNPA1P64, AL596276.1, AL596276.2, AL136234.1, LINC01781.
- chr1:103,414,879–121,580,524, 395 genes (broad region; genes not listed).
- chr2:235,494,043–236,131,800, 6 genes (within-gene range 0–2): AGAP1, AGAP1-IT1, AC064874.1, TMSB10P1, RNU7-127P, RN7SL204P.
- chr3:19,879,472–20,012,606, 7 genes: EFHB, HSPA8P18, RAB5A, PP2D1, RNU4-85P, SAP18P3, RPL39P18.
- chr3:59,747,277–61,251,459, 8 genes (within-gene range 0–1): FHIT, AC093418.1, AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71, U3.
- chr4:105,526,596–105,552,355, 3 genes: PIMREGP2, ATP5F1EP1, AC004066.1.
- chr4:105,561,591–105,570,238, 1 gene (within-gene range 0–1): ARHGEF38-IT1.
- chr4:189,472,965–189,475,192, 1 gene: HSP90AA4P.
- chr5:60,021,249–60,033,020, 1 gene (within-gene range 0–2): AC034234.1.
- chr6:21,485,896–21,523,783, 2 genes: LINC00581, AL512380.1.
- chr6:168,194,358–168,240,715, 3 genes: AL611929.1, AL606970.4, AL606970.2.
- chr8:89,585,872–89,791,064, 2 genes: AF117829.1, RIPK2.
- chr10:14,061–19,793,101, 318 genes (broad region; genes not listed).
- chr10:79,660,891–79,826,594, 7 genes (within-gene range 0–1): AL132656.2, NUTM2B-AS1, AL132656.3, AL132656.4, BEND3P3, AL132656.1, NUTM2B.
- chr15:20,729,747–20,866,314, 11 genes: AC012414.4, RNU6-498P, AC012414.2, AC012414.3, LONRF2P3, AC012414.6, GRAMD4P5, AC012414.1, MIR3118-2, POTEB2, RNU6-749P.
- chr15:20,901,441–20,901,609, 1 gene: ZNF519P2.
- chr15:20,940,380–21,058,440, 3 genes (within-gene range 0–1): LINC01193, OR11J2P, OR11J5P.
- chr18:45,034–4,455,307, 99 genes (broad region; genes not listed).
- chr18:4,775,054–80,247,514, 1,099 genes (broad region; genes not listed).
- chr19:20,249,052–20,303,794, 4 genes (within-gene range 0–1): AC078899.3, AC078899.1, BNIP3P18, AC078899.4.
- chr19:20,416,514–20,571,095, 3 genes (within-gene range 0–1): BNIP3P22, AC008554.1, BNIP3P23.
- chr20:14,757,563–14,758,056, 1 gene (within-gene range 0–1): RPS10P2.
- chr20:14,933,843–15,280,873, 4 genes (within-gene range 0–1): AL138808.1, RNU6-1159P, RNU6-115P, RNA5SP475.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 7,327 genes in 52 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–248,937,043, 2,524 genes, copy number 3–5 (broad region; genes not listed).
- chr6:105,919–351,355, 8 genes, copy number 3: OR4F1P, CICP18, AL035696.2, AL035696.3, AL035696.4, AL035696.1, AL365272.1, DUSP22.
- chr6:143,386,581–144,853,034, 29 genes, copy number 3: AL031320.1, ADAT2, TUBB8P2, RNA5SP221, PEX3, AL031320.2, VDAC1P8, FUCA2, PHACTR2, PHACTR2-AS1, AL049844.1, LTV1, AL049844.3, AL049844.2, ZC2HC1B, PLAGL1, HYMAI, AL109755.2, AL109755.1, SF3B5, MRPL42P3, STX11, TPT1P4, AL024474.1, UTRN, AL024474.2, AL590704.1, AL513475.1, AL513475.2.
- chr6:152,121,684–152,637,801, 4 genes, copy number 3 (within-gene range 2–3): SYNE1, SYNE1-AS1, AL049548.1, RNA5SP223.
- chr6:152,898,047–153,427,154, 11 genes, copy number 3: TUBB4BP7, AL080276.1, FBXO5, AL080276.2, MTRF1L, RGS17, RNA5SP224, AL590867.1, AL590867.2, AL358134.1, RNA5SP225.
- chr6:155,654,963–156,397,589, 3 genes, copy number 3 (within-gene range 2–3): RNU7-152P, AL589693.1, MIR1202.
- chr6:158,609,706–158,926,571, 13 genes, copy number 3 (within-gene range 2–3): TATDN2P2, MIR7161, DYNLT1, SYTL3, AMZ2P2, MIR3918, EZR, EZR-AS1, OSTCP1, AL627422.2, C6orf99, AL627422.1, RNU6-293P.
- chr6:160,872,888–164,009,980, 25 genes, copy number 3: AL391361.2, AL391361.1, AL139393.2, AL139393.1, MAP3K4-AS1, MAP3K4, AGPAT4, PRKN, AL132982.1, AL138716.1, KRT8P44, PACRG, AL590286.1, AL590286.2, PACRG-AS2, AL137182.1, PACRG-AS3, PACRG-AS1, AL031121.1, CAHM, QKI, AL445307.1, AL078602.1, AL137005.1, RN7SL366P.
- chr6:164,827,732–166,209,506, 15 genes, copy number 3: AL450345.1, AL136100.1, C6orf118, PDE10A, RNA5SP226, RNU6-730P, AL590302.2, AL590302.1, LINC00602, GAPDHP72, AL627443.1, AL627443.2, TBXT, LNCDAT, RNU6-153P.
- chr6:169,213,254–170,738,536, 37 genes, copy number 3: BX322234.1, THBS2, BX322234.2, VTA1P1, LINC02519, AL031315.1, AL135910.1, WDR27, C6orf120, PHF10, AL354892.2, AL354892.1, TCTE3, ERMARD, AL354892.3, LINC00242, LINC00574, AL049612.1, AL596442.1, AL596442.2, RPL12P23, AL109910.1, AL109910.2, LINC01624, DLL1, FAM120B, AL078605.1, MIR4644, AL008628.1, PSMB1, TBP, PDCD2, AL672310.1, OR4F7P, WBP1LP8, AL731661.1, AL731684.1.
- chr7:37,032–95,683, 3 genes, copy number 3: AC215522.1, AC093627.1, AC093627.6.
- chr7:38,239,580–38,350,022, 19 genes, copy number 3 (within-gene range 2–3): TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6, TRGV5P, TRGV5.
- chr7:82,589,848–84,492,724, 10 genes, copy number 3: MTHFD2P5, AC004006.1, PCLO, RNA5SP235, AC079799.1, SEMA3E, AC079799.2, AC079987.1, RAD23BP2, SEMA3A.
- chr7:95,772,506–96,377,920, 9 genes, copy number 3: DYNC1I1, AC002540.1, SLC25A13, MIR591, AC096775.1, AC084368.1, RNU6-532P, RNU6-364P, RNU7-188P.
- chr7:104,940,943–105,399,308, 12 genes, copy number 3: AC007384.1, LINC01004, KMT2E-AS1, KMT2E, AC005070.3, SRPK2, AC005070.1, AC005070.2, AC004884.1, RWDD4P1, AC004884.2, RNU6-1322P.
- chr7:115,503,367–115,581,442, 2 genes, copy number 3: POLR2DP2, SNORA25B.
- chr7:121,348,878–122,310,691, 15 genes, copy number 3: FAM3C, CYCSP19, AC074085.1, AC074085.2, AC004875.1, RN7SKP277, PNPT1P2, PTPRZ1, AASS, RNU7-154P, AC015983.2, AC006020.1, AC015983.1, FEZF1, FEZF1-AS1.
- chr7:125,229,579–125,346,197, 4 genes, copy number 3: AC019155.2, AC010099.1, AC010099.2, PPIAP93.
- chr7:134,284,500–134,350,791, 3 genes, copy number 3: AC008154.2, SLC35B4, AC008154.1.
- chr7:136,868,669–137,164,612, 4 genes, copy number 3: CHRM2, MIR490, KRT8P51, AC009517.1.
- chr7:141,052,249–142,408,136, 56 genes, copy number 3: RNU4-74P, TMEM178B, AC006362.1, NDUFB10P2, AC005692.3, AC005692.1, AC005692.2, AC073878.1, AC073878.2, AGK, AC004918.1, DENND11, AC004918.3, WEE2-AS1, WEE2, RNU1-82P, SSBP1, TAS2R3, TAS2R4, TAS2R6P, TAS2R5, MTCO1P55, MTND2P5, MTND1P3, MYL6P4, PRSS37, OR9A3P, OR9A1P, MGAM, OR9N1P, OR9A4, CLEC5A, TAS2R38, MGAM2, MOXD2P, PRSS58, TRY2P, AC245088.1, PRSS3P3, TRBV1, TRBV2, TRBV3-1, TRBV4-1, TRBV5-1, TRBV6-1, TRBV7-1, TRBV4-2, TRBV8-1, TRBV5-2, TRBV6-4, TRBV7-3, TRBV8-2, TRBV5-3, TRBV9, TRBV10-1, TRBV11-1.
- chr7:149,285,281–149,734,575, 9 genes, copy number 3: AC004890.2, AC004941.2, NPM1P12, AC004941.1, AC073314.1, ZNF777, ZNF746, ZNF767P, KRBA1.
- chr7:152,644,776–152,855,378, 4 genes, copy number 3: XRCC2, ATP5PBP3, RN7SL845P, ACTR3B.
- chr7:155,611,231–159,233,377, 52 genes, copy number 3: AC009403.1, RBM33, SHH, AC021218.1, Y_RNA, AC093813.1, LINC01006, LINC00244, AC005534.1, RNF32, RNF32-AS1, LMBR1, RNU4-31P, AC006357.1, NOM1, MNX1, MNX1-AS2, MNX1-AS1, AC006967.2, AC006967.1, AC006967.3, UBE3C, RPS27AP12, AC004898.1, AC004975.1, AC004975.2, DNAJB6, AC006372.3, AC006372.1, AC006372.2, AC006372.4, PTPRN2, MIR153-2, AC005481.1, AC006003.1, PTPRN2-AS1, AC011899.2, AC011899.3, AC011899.1, MIR595, AC078942.1, LINC01022, MIR5707, THAP5P1, NCAPG2, AC019084.1, ESYT2, DYNC2I1, LINC00689, VIPR2, AC007269.1, PIP5K1P2.
- chr13:18,467,172–114,337,626, 1,330 genes, copy number 3–5 (broad region; genes not listed).
- chr14:21,894,433–22,505,167, 80 genes, copy number 3 (broad region; genes not listed).
- chr16:11,555–3,717,553, 338 genes, copy number 3–4 (broad region; genes not listed).
- chr16:7,726,841–14,707,055, 156 genes, copy number 3 (broad region; genes not listed).
- chr16:15,037,854–35,912,516, 807 genes, copy number 3 (broad region; genes not listed).
- chr16:52,005,487–52,099,120, 5 genes, copy number 3: C16orf97, AC009039.1, AC009039.2, LINC00919, LINC02180.
- chr16:58,157,907–58,734,342, 23 genes, copy number 3 (within-gene range 2–3): CSNK2A2, AC009107.1, RN7SL645P, CCDC113, PRSS54, GINS3, RNU6-269P, AC009118.1, RNU6-1110P, AC009118.2, LINC02137, NDRG4, RNU6-103P, SETD6, CNOT1, AC009118.3, SNORA46, SNORA50A, SNORA50A, AC010287.1, SLC38A7, AC012183.1, GOT2.
- chr16:60,925,733–61,055,964, 2 genes, copy number 3: AC009169.1, RPS27AP16.
- chr16:66,366,622–67,563,958, 77 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr16:70,454,595–70,801,160, 15 genes, copy number 3: FCSK, COG4, SF3B3, SNORD111B, SNORD111, IL34, MTSS2, AC020763.4, VAC14, AC020763.3, AC020763.1, VAC14-AS1, AC020763.5, AC020763.2, AC027281.1.
- chr16:71,929,538–73,891,871, 34 genes, copy number 3 (within-gene range 2–3): PKD1L3, RPL39P31, AC009127.2, ATP5F1AP3, DHODH, TXNL4B, HP, HPR, AC009087.1, DHX38, PMFBP1, AC009075.1, LINC01572, AC009075.2, U6, AC004158.1, AC004943.2, RNU7-90P, KRT18P18, AC004943.3, ZFHX3, AC004943.1, RNU7-71P, AC132068.1, AC002044.3, AC002044.1, AC002044.2, AC116667.1, HCCAT5, AC116667.2, AC140912.1, AC009033.1, LINC01568, AC092114.1.
- chr16:79,212,711–79,677,715, 8 genes, copy number 3 (within-gene range 2–3): AC092376.1, RNA5SP431, AC084064.1, MAF, AC009159.2, AC009159.3, AC009159.1, AC009159.4.
- chr16:83,789,967–85,690,073, 52 genes, copy number 3 (within-gene range 2–3): AC009119.1, HSBP1, MLYCD, AC009119.2, OSGIN1, NECAB2, SLC38A8, RNA5SP432, AC040169.4, MBTPS1, AC040169.3, AC040169.1, AC040169.2, HSDL1, DNAAF1, TAF1C, ADAD2, AC009123.1, KCNG4, AC010551.3, RNA5SP433, WFDC1, AC010551.2, AC010551.1, ATP2C2, ATP2C2-AS1, MEAK7, AC022165.1, COTL1, AC092145.1, KLHL36, USP10, AC025280.3, CRISPLD2, AC025280.1, AC025280.2, LINC02176, ZDHHC7, KIAA0513, CIBAR2, LINC02139, AC026469.1, GSE1, AC092275.1, COX6CP16, LINC00311, MIR5093, AC133540.1, AC092127.2, AC092127.1, RN7SL381P, GINS2.
- chr17:27,756,766–30,186,475, 145 genes, copy number 3 (broad region; genes not listed).
- chr17:37,375,985–42,440,259, 266 genes, copy number 4–19 (broad region; genes not listed).
- chr20:16,177,933–64,327,972, 1,106 genes, copy number 3–4 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 25,658. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
